Somatic mutation profile of tumor specimen TCGA-27-1832-01A (aliquot TCGA-27-1832-01A-01W-0643-08) from TCGA case TCGA-27-1832, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.4 years (21,678 days).
Specimen TCGA-27-1832-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4cbbc83-f242-418e-b8e0-421d96ca6cff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-27-1832-10A (Blood Derived Normal), aliquot TCGA-27-1832-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52d7f132-edd2-4592-81af-7c638a01b49b

The open-access MAF lists 44 somatic variants for this specimen: 36 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 29, Silent 8, Frame Shift Ins 4, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TMPRSS6 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs387907018, CM093222, COSV60977986, COSV60980115; ClinVar: pathogenic; called by muse, varscan2
- TRPV4 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs267607145, CM100594, COSV55681642; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCC8 | c.4522A>C p.T1508P | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs80075294; called by muse, mutect2
- ATP6V0A4 | c.734C>A p.T245N | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.876); catalogued as COSV59475565; called by muse, mutect2
- CD163L1 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 64/297 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs757615416, COSV58015867; called by muse, mutect2, varscan2
- CDKN2A | c.367C>A p.H123N | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV58709909; called by muse, mutect2
- CDR1 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.914); catalogued as rs143948461, COSV65164205; called by muse, mutect2, varscan2
- CNTNAP3 | c.2944dup p.V982Gfs*4 | Frame Shift Ins (INS) | VAF 12/49 reads (24%) | catalogued as rs763585044; called by mutect2, pindel, varscan2
- COL5A2 | c.2519G>A p.G840E | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66409657; called by muse, mutect2, varscan2
- CPS1 | c.286A>G p.M96V | Missense Mutation (SNP) | VAF 91/337 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs1432483864, COSV51809640; called by muse, mutect2, varscan2
- CUBN | c.7514G>T p.C2505F | Missense Mutation (SNP) | VAF 18/382 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1564420487, COSV64708611; called by muse, mutect2
- DSEL | c.773A>G p.N258S | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0.014); catalogued as COSV59491398; called by muse, mutect2, varscan2
- DUS1L | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760210278, COSV60784523; called by muse, mutect2, varscan2
- ENPP7 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs782232450, COSV60386457; called by muse, mutect2, varscan2
- GLS | c.917A>T p.H306L | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57841957; called by muse, mutect2
- GPR107 | c.598A>G p.N200D | Missense Mutation (SNP) | VAF 106/350 reads (30%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV61279345; called by muse, mutect2, varscan2
- IPO5 | c.2209C>T p.R737C | Missense Mutation (SNP) | VAF 38/350 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1383579161, COSV55154409; called by muse, mutect2, varscan2
- JADE3 | c.2286G>C p.Q762H | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.4); catalogued as COSV54466414; called by muse, mutect2, varscan2
- KATNIP | c.2908G>A p.V970I | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as rs374130852; called by muse, mutect2, varscan2
- KLK15 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs140896741; called by muse, mutect2, varscan2
- MAP7D3 | c.922dup p.Q308Pfs*25 | Frame Shift Ins (INS) | VAF 12/102 reads (12%) | catalogued as rs746202015; called by mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 24/142 reads (17%) | catalogued as rs777328830; called by mutect2, varscan2
- PLCXD2 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 9/196 reads (5%) | catalogued as COSV101210102; called by muse, mutect2
- PPRC1 | c.4382dup p.H1462Tfs*10 | Frame Shift Ins (INS) | VAF 20/168 reads (12%) | catalogued as rs772864639; called by mutect2, varscan2
- SLC38A10 | c.1638_1641del p.E548Nfs*156 (on ENST00000374759 / NM_001037984.3; = p.E548Nfs*? on NM_138570.4) | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs777968247; called by mutect2, pindel, varscan2
- SLC7A7 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV53537073; called by muse, varscan2
- SMCR8 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.248); catalogued as COSV58177300; called by muse, mutect2, varscan2
- TRIM72 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV59067734; called by muse, mutect2, varscan2
- USP28 | c.1357A>G p.S453G | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV50162501; called by muse, mutect2, varscan2
- WDFY3 | c.6823C>T p.R2275C | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1306992677, COSV55700591; called by muse, mutect2, varscan2
- AREL1 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ARFIP1 | c.248T>C p.V83A | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- EMC1 | c.1243G>T p.D415Y | Missense Mutation (SNP) | VAF 42/715 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2
- FAM32A | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- GOLPH3L | c.588del p.K196Nfs*4 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | called by mutect2, varscan2
- MCM6 | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 12/283 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- AACS | c.966C>A p.T322= | Silent (SNP) | VAF 43/167 reads (26%) | catalogued as COSV55536586; called by muse, mutect2, varscan2
- C9orf131 | c.3039G>A p.S1013= | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as rs777801222; called by muse, mutect2, varscan2
- CROT | c.585G>T p.L195= | Silent (SNP) | VAF 83/575 reads (14%) | catalogued as COSV58974190; called by muse, mutect2, varscan2
- F10 | c.261C>T p.G87= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs763365831, COSV65021693; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MS4A6A | c.228C>T p.T76= | Silent (SNP) | VAF 54/171 reads (32%) | catalogued as COSV100125121, COSV60618495, COSV60621857; called by muse, mutect2, varscan2
- PCDHA1 | c.1332G>A p.E444= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV65374254; called by muse, mutect2, varscan2
- RP9 | c.237C>T p.H79= | Silent (SNP) | VAF 109/468 reads (23%) | catalogued as rs374773345, COSV51806869; called by muse, mutect2, varscan2
- THBS1 | c.654C>A p.V218= | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as COSV52956005; called by muse, mutect2
